Somatic mutation profile of tumor specimen RC-B65N-TBP1-B (aliquot RC-B65N-TBP1-B-1-0-D-A93N-47) from RC case RC-B65N, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: female; Vital status: Alive; Primary diagnosis: T-cell large granular lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 69.1 years (25,246 days).
Specimen RC-B65N-TBP1-B: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88d39524-56cd-4e10-bfd1-0b65a64fc358.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen RC-B65N-NB1-A (Granulocytes; tissue type Normal), aliquot RC-B65N-NB1-A-1-0-D-A93N-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af533699-5631-4063-ba9b-645f09ab6000

The open-access MAF lists 14 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 11, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACCSL | c.943C>T p.L315F | Missense Mutation (SNP) | VAF 54/159 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.02); catalogued as rs1347425521; called by muse, mutect2, varscan2
- INPP4A | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 58/140 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs762110602; called by muse, mutect2, varscan2
- RIPK1 | c.1709C>T p.A570V | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV52528012; called by muse, mutect2, varscan2
- XKR4 | c.1676G>A p.R559H | Missense Mutation (SNP) | VAF 69/204 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.828); catalogued as rs137920953; called by muse, mutect2, varscan2
- ZNF236 | c.4706T>G p.L1569R | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53489555; called by muse, varscan2
- HFM1 | c.398G>A p.G133D | Missense Mutation (SNP) | VAF 45/170 reads (26%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- JPH1 | c.625G>T p.G209C | Missense Mutation (SNP) | VAF 35/227 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- MYO9A | c.1043A>T p.D348V | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- NPHP3 | c.2404C>T p.L802F | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.34); called by muse, mutect2
- NXPE2 | c.861C>A p.F287L | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ZNF711 | c.2283G>A p.M761I | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); called by muse, varscan2
- CD200R1 | c.771C>A p.I257= (on ENST00000471858 / NM_170780.3; = p.I280= on NM_138806.4) | Silent (SNP) | VAF 14/99 reads (14%) | catalogued as COSV55600674; called by muse, mutect2, varscan2
- HIPK1 | c.2610G>A p.G870= | Silent (SNP) | VAF 34/122 reads (28%) | called by muse, mutect2, varscan2
- MTNR1B | c.33C>T p.C11= | Silent (SNP) | VAF 83/245 reads (34%) | catalogued as rs1315411833; called by muse, mutect2, varscan2
